Somatic mutation profile of tumor specimen TARGET-40-NAAIBU-01A (aliquot TARGET-40-NAAIBU-01A-01D) from TARGET case TARGET-40-NAAIBU, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 7.2 years (2,628 days).
Specimen TARGET-40-NAAIBU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87eaa351-c3d7-46f6-96c5-9ffd199b1189.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAIBU-10B (Blood Derived Normal), aliquot TARGET-40-NAAIBU-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51d3c96e-a65f-489e-8d6b-bc5f568cfe84

The open-access MAF lists 135 somatic variants for this specimen: 100 protein-altering or splice-affecting, 21 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 21, Intron 7, Splice Region 4, 3'Flank 4, Nonsense Mutation 2, RNA 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs28942075, CM123054, CM950110; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C3orf56 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371883407; called by muse, mutect2, varscan2
- CCDC96 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV59508266; called by muse, mutect2, varscan2
- CNTNAP5 | c.1931G>C p.G644A | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV70482037; called by muse, mutect2, varscan2
- COL6A5 | c.7176G>C p.W2392C (on ENST00000312481; = p.W2388C on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55201261; called by muse, mutect2, varscan2
- CPNE8 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs773604055, COSV58841626; called by muse, mutect2
- GABRG2 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100729814; called by muse, mutect2, varscan2
- GRIP2 | c.2525G>A p.R842H (on ENST00000619221; = p.R745H on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs376032044; called by mutect2, varscan2
- HAL | c.855C>T p.Y285= | Splice Region (SNP) | VAF 51/200 reads (26%) | catalogued as rs201094537, COSV99701379; called by muse, varscan2
- HHLA1 | c.139+7G>A | Splice Region (SNP) | VAF 38/95 reads (40%) | catalogued as rs1341574358; called by muse, mutect2, varscan2
- KLHL1 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1566582336; called by muse, mutect2, varscan2
- MPZL1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100850418; called by muse, mutect2, varscan2
- NLGN1 | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV64325289; called by muse, mutect2, varscan2
- NVL | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV55869896; called by muse, mutect2, varscan2
- ODF2 | c.1752G>C p.A584= (on ENST00000434106 / NM_153433.2; = p.A560= on NM_002540.5 and 4 other RefSeq transcripts) | Splice Region (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100654550, COSV63546324; called by muse, mutect2, varscan2
- POU6F1 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1185281066; called by muse, mutect2, varscan2
- PTPRB | c.704T>C p.M235T | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs776085240; called by muse, mutect2, varscan2
- PXN | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99935570; called by muse, mutect2, varscan2
- PYROXD2 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1353085911; called by mutect2, varscan2
- RB1 | c.219_220dup p.A74Efs*4 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as COSV57297594; called by mutect2, varscan2
- SACS | c.5302C>T p.H1768Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs758381112, COSV101207484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5B | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1350473776; called by muse, mutect2, varscan2
- SLC35F6 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs755557241; called by muse, mutect2, varscan2
- SMIM21 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV66895473; called by muse, varscan2
- TBCD | c.2424C>G p.D808E | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV62799808; called by muse, mutect2
- ZNF793 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV71325154; called by muse, mutect2
- AARD | c.102C>G p.C34W | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ACHE | c.1507T>A p.F503I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- ADA | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 155/420 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADCY3 | c.3154G>C p.G1052R | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK7 | c.2038del p.L680* | Frame Shift Del (DEL) | VAF 31/65 reads (48%) | called by mutect2, pindel, varscan2
- ALOX15B | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AMPH | c.418A>T p.R140W | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG16L1 | c.794+4A>G | Splice Region (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- BNIP2 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1B | c.3385T>C p.S1129P | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACNB1 | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- CASC3 | c.9C>G p.D3E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CCDC168 | c.13582T>C p.S4528P | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- CLUH | c.2738A>G p.E913G (on ENST00000435359; = p.E952G on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CORO2A | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- DVL1 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FLG2 | c.1059A>C p.R353S | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GASK1A | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GGA2 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GJA8 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GNPTAB | c.294A>T p.E98D | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GPR50 | c.593T>G p.V198G | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GPR50 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- H4C5 | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HECTD4 | c.5317G>C p.A1773P | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOMER2 | c.827T>C p.I276T (on ENST00000304231 / NM_199330.3; = p.I265T on NM_004839.4) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- IGSF9 | c.3107C>A p.P1036H (on ENST00000368094 / NM_001135050.2; = p.P1020H on NM_020789.4) | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IVL | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- KANK2 | c.1168C>G p.P390A | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KCNA7 | c.1261T>G p.C421G | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIAA0825 | c.2615G>T p.S872I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- KIF20A | c.2537A>G p.K846R | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP4 | c.5221A>G p.I1741V | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- LRRK2 | c.4171A>C p.N1391H | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRN4CL | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- MATK | c.246G>T p.E82D (on ENST00000310132 / NM_139355.3; = p.E83D on NM_002378.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- MATK | c.245A>T p.E82V (on ENST00000310132 / NM_139355.3; = p.E83V on NM_002378.4) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- METTL2B | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYPN | c.3001A>T p.T1001S | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEK9 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC5 | c.5155G>A p.E1719K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NUP210 | c.4761C>A p.N1587K | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- OR1Q1 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- OTX1 | c.802G>C p.A268P | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PCCA | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2
- PHKA1 | c.1715A>T p.D572V | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PHLDB1 | c.803C>A p.A268D | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- PILRB | c.296T>A p.L99Q | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIR | c.831del p.F278Lfs*22 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- PPP3R1 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTCHD4 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- PYROXD2 | c.471+1G>T p.X157_splice | Splice Site (SNP) | VAF 49/81 reads (60%) | called by muse, mutect2, varscan2
- RASSF7 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RDM1 | c.854A>G p.*285Wext*3 | Nonstop Mutation (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- RIPOR1 | c.287A>G p.H96R (on ENST00000379312 / NM_001193522.2; = p.H92R on NM_024519.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RNF167 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SEC14L6 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SEMA5B | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SH3RF2 | c.607A>T p.K203* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- SLC7A7 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMC1B | c.707A>G p.H236R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSX1 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- TBXT | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TFCP2 | c.1347C>A p.S449R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TTC9B | c.478T>G p.C160G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UTP6 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZGRF1 | c.5306A>T p.E1769V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- ZMYND12 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZMYND8 | c.1864G>T p.G622C (on ENST00000311275 / NM_001363741.2; = p.G642C on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZNF333 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 147/371 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF341 | c.1784A>T p.K595M (on ENST00000375200 / NM_001282935.1; = p.K588M on NM_032819.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- ZNF404 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF560 | c.1579T>A p.S527T | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2
- ZNF727 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BUB1B | c.3078A>G p.T1026= | Silent (SNP) | VAF 48/173 reads (28%) | called by muse, mutect2, varscan2
- CLSTN1 | c.1536A>G p.E512= (on ENST00000377298 / NM_001009566.3; = p.E502= on NM_014944.4) | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- DDX11 | c.2697A>T p.G899= (on ENST00000545668 / NM_152438.2; = p.E851V on NM_004399.3) | Silent (SNP) | VAF 84/301 reads (28%) | called by muse, mutect2, varscan2
- FILIP1 | c.3597A>G p.K1199= | Silent (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- GET4 | c.648C>T p.F216= | Silent (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- HEATR6 | c.294C>T p.S98= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- KCTD2 | c.309C>T p.C103= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1025214265; called by muse, varscan2
- KLF17 | c.1080A>G p.Q360= | Silent (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
- LCP2 | c.1470A>G p.R490= | Silent (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- MTSS1 | c.906C>T p.R302= | Silent (SNP) | VAF 83/349 reads (24%) | called by muse, mutect2, varscan2
- MYT1L | c.1428G>A p.E476= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs1486479032; called by muse, mutect2
- OR4L1 | c.828A>T p.T276= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV59849493; called by muse, mutect2, varscan2
- PIK3R2 | c.1410C>G p.T470= | Silent (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- SCGB2A1 | c.9G>T p.L3= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs1303699850; called by muse, mutect2, varscan2
- SGSM1 | c.1188A>C p.R396= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV68510319; called by muse, mutect2, varscan2
- TF | c.1773G>A p.E591= | Silent (SNP) | VAF 41/188 reads (22%) | catalogued as rs767755375, COSV53923501; called by muse, mutect2, varscan2
- TRPV2 | c.2283C>T p.L761= | Silent (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
- USF3 | c.6069T>C p.I2023= | Silent (SNP) | VAF 63/195 reads (32%) | called by muse, mutect2, varscan2
- WDR90 | c.3039A>G p.P1013= | Silent (SNP) | VAF 89/119 reads (75%) | called by muse, mutect2, varscan2
- ZNF208 | c.336C>T p.H112= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- ZYG11A | c.1626T>C p.N542= | Silent (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- COX11 | c.*1466T>G | 3'UTR (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+144C>G | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as rs1188159880; called by muse, mutect2, varscan2
- MYO7A | c.3503+131T>G | Intron (SNP) | VAF 46/198 reads (23%) | called by muse, mutect2, varscan2
- PROC | c.263-18C>A | Intron (SNP) | VAF 44/149 reads (30%) | called by muse, mutect2, varscan2
- RASA4CP | n.272G>T | RNA (SNP) | VAF 29/305 reads (10%) | catalogued as rs191247957; called by muse, mutect2
- SHANK2 | c.2551+40G>C | Intron (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- SLC37A3 | c.703+125G>A | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1258C>G | RNA (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- STXBP2 | c.247-374T>A | Intron (SNP) | VAF 103/324 reads (32%) | called by muse, mutect2, varscan2
- TAFA2 | c.-1-10658C>A | Intron (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16439567 C>T | 3'Flank (SNP) | VAF 64/374 reads (17%) | called by muse, varscan2
- TRPV2 | chr17:16439653 C>G | 3'Flank (SNP) | VAF 69/408 reads (17%) | catalogued as rs147936849; called by muse, varscan2
- TRPV2 | chr17:16441303 C>G | 3'Flank (SNP) | VAF 29/230 reads (13%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16441443 C>T | 3'Flank (SNP) | VAF 51/278 reads (18%) | called by muse, mutect2, varscan2
